MMRF case MMRF_1224 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7e67c911-7873-4714-bef5-f732f6bb29d6

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.1 years (23,038 days); ISS stage: III; Days to last known disease status: 1,613 days (4.4 years); Days to last follow up: 1,613 days (4.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 203 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 226 days; Days to treatment end: 1,040 days (2.8 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,056 days (2.9 years); Days to treatment end: 1,056 days (2.9 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 1,057 days (2.9 years); Days to treatment end: 1,057 days (2.9 years).
   Treatment given: Therapeutic agents: Dexamethasone + Elotuzumab + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,178 days (3.2 years); Days to treatment end: 1,492 days (4.1 years).
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,525 days (4.2 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,550 days (4.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -1: M Protein 3.23 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.895 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 42.8 mg/dL; Immunoglobulin G 36.6 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 8.95 µg/mL; Lactate Dehydrogenase 4.32 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.03 ×10⁹/L; Platelets 84 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.03 mmol/L; Albumin 25 g/L; Total Protein 7.8 g/dL; Glucose 8.31 mmol/L; C-Reactive Protein 0.23 mg/dL.
- Day 63 (ECOG 0): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.901 mg/dL; Immunoglobulin G 7.35 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.35 g/L; Lactate Dehydrogenase 4.45 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.05 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.05 mmol/L; Albumin 34 g/L; Total Protein 5.6 g/dL; Glucose 5.28 mmol/L.
- Day 161 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.838 mg/dL; Immunoglobulin G 6.83 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.46 g/L; Lactate Dehydrogenase 3.8 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.67 mmol/L.
- Day 280 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.91 mg/dL; Immunoglobulin G 9.43 g/L; Immunoglobulin A 0.91 g/L; Immunoglobulin M 0.38 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 1.98 mmol/L; Albumin 36 g/L; Total Protein 6.3 g/dL; Glucose 5.34 mmol/L.
- Day 392 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 8.22 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.65 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.98 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 5.72 mmol/L.
- Day 498 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Immunoglobulin G 7.52 g/L; Immunoglobulin A 1.25 g/L; Immunoglobulin M 0.81 g/L; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 6.55 mmol/L.
- Day 554 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 8.66 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.78 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.4 mmol/L; Albumin 36 g/L; Total Protein 6.5 g/dL; Glucose 5.39 mmol/L.
- Day 645 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 9.26 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.3 g/dL; Glucose 7.1 mmol/L.
- Day 720 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 9.5 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.51 g/L; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 192 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 4.95 mmol/L.
- Day 811 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.51 mg/dL; Immunoglobulin G 9.56 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 98.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6.9 g/dL; Glucose 3.91 mmol/L.
- Day 902 (ECOG 0): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.94 mg/dL; Immunoglobulin G 9.37 g/L; Immunoglobulin A 1.56 g/L; Immunoglobulin M 0.72 g/L; Lactate Dehydrogenase 3.62 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 5.06 mmol/L.
- Day 1,002 (ECOG 1): M Protein 0.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 7.72 g/L; Immunoglobulin A 0.76 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.35 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.67 mmol/L.
- Day 1,037 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 6.01 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.36 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 6.55 mmol/L.
- Day 1,134 (ECOG 0): M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 8.44 g/L; Immunoglobulin A 0.63 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 5.45 mmol/L.
- Day 1,246 (ECOG 0): M Protein 0.22 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 6.86 g/L; Immunoglobulin A 0.75 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 6.22 mmol/L.
- Day 1,338 (ECOG 1): M Protein 0.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.85 mg/dL; Immunoglobulin G 7.68 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.62 g/L; Beta 2 Microglobulin 3.48 µg/mL; Lactate Dehydrogenase 6.08 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.12 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 5.61 mmol/L.
- Day 1,464 (ECOG 0): M Protein 0.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.14 mg/dL; Immunoglobulin G 10.1 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 4.43 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 5.6 g/dL; Glucose 10.1 mmol/L.
- Day 1,554 (ECOG 1): M Protein 1.08 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.713 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.9 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.16 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 7.32 mmol/L.
- Day 1,613 (ECOG 1): M Protein 0.89 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 15.4 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.33 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 6.05 mmol/L.

Other clinical attributes
- Day -1: Weight: 80 kg; Height: 182 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1224_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -1 day.
- Sample MMRF_1224_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -1 day.
